Somatic mutation profile of tumor specimen ALCH-B1KM-TTP1-A (aliquot ALCH-B1KM-TTP1-A-6-0-D-A710-36) from ALCHEMIST case ALCH-B1KM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.2 years (29,287 days).
Specimen ALCH-B1KM-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75f1a8f3-80c2-4dc1-9810-e1d644a1c4ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1KM-NB1-A (Blood Derived Normal), aliquot ALCH-B1KM-NB1-A-1-0-D-A710-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7ca0565-8253-4bd6-bc8b-f5ff0b354b72

The open-access MAF lists 56 somatic variants for this specimen: 43 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 10, Nonsense Mutation 3, Intron 2, Frame Shift Del 2, In Frame Del 2, Nonstop Mutation 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 176/671 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- ACSS2 | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 19/576 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV53625787, COSV53628459; called by muse, mutect2
- BTG3 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 45/468 reads (10%) | catalogued as rs373951463, COSV60286895; called by muse, mutect2
- CNKSR2 | c.431G>T p.R144M | Missense Mutation (SNP) | VAF 32/634 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54252639; called by muse, mutect2
- DEAF1 | c.69_98del p.A24_A33del | In Frame Del (DEL) | VAF 7/51 reads (14%) | catalogued as rs754135731; called by mutect2, varscan2*
- DOCK3 | c.2795G>A p.R932Q | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as rs1283527925; called by muse, mutect2, varscan2
- ECI2 | c.443del p.D148Vfs*17 (on ENST00000380118 / NM_206836.3; = p.D118Vfs*17 on NM_006117.2) | Frame Shift Del (DEL) | VAF 75/311 reads (24%) | catalogued as COSV60988439; called by mutect2, pindel, varscan2
- GIGYF2 | c.3898T>A p.*1300Rext*61 | Nonstop Mutation (SNP) | VAF 47/452 reads (10%) | catalogued as rs758525899; called by muse, mutect2
- GRPR | c.782G>T p.R261L | Missense Mutation (SNP) | VAF 67/624 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100977625; called by muse, mutect2, varscan2
- MXRA5 | c.3962C>G p.S1321* | Nonsense Mutation (SNP) | VAF 8/162 reads (5%) | catalogued as COSV54234563; called by muse, mutect2
- OR56A5 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV60827222; called by muse, mutect2, varscan2
- PARP10 | c.2462A>T p.E821V | Missense Mutation (SNP) | VAF 23/168 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs781860987, COSV100477881; called by muse, mutect2, varscan2
- PROP1 | c.80C>T p.P27L | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs368561632, COSV57644705; called by muse, mutect2, varscan2
- SELENOP | c.8G>A p.R3K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1317810742; called by muse, mutect2
- SH3GL2 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV66051588; called by muse, mutect2
- SLC17A3 | c.474C>G p.I158M | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100399151; called by muse, mutect2
- TBL1X | c.1558T>G p.L520V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.491); catalogued as COSV54274794; called by muse, mutect2
- TRIM39 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 26/270 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs767399572; called by muse, mutect2
- UGGT2 | c.334A>G p.I112V | Missense Mutation (SNP) | VAF 17/205 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs781047282; called by muse, mutect2
- ADGRB1 | c.2666A>C p.E889A | Missense Mutation (SNP) | VAF 38/218 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- AMELX | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 124/525 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- ANTXRL | c.806A>T p.H269L | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.093); called by muse, mutect2
- CCDC168 | c.801C>A p.S267R | Missense Mutation (SNP) | VAF 17/307 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2
- CCDC175 | c.1051_1053del p.H351del | In Frame Del (DEL) | VAF 44/214 reads (21%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.431+1G>T p.X144_splice | Splice Site (SNP) | VAF 32/630 reads (5%) | called by muse, mutect2
- ERCC3 | c.1855G>T p.E619* | Nonsense Mutation (SNP) | VAF 48/471 reads (10%) | called by muse, mutect2, varscan2
- IGBP1P2 | c.793G>T p.A265S | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- MAP7D2 | c.2071G>C p.D691H | Missense Mutation (SNP) | VAF 42/662 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MDM2 | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 25/512 reads (5%) | SIFT tolerated (0.92); PolyPhen benign (0.013); called by muse, mutect2
- NRXN2 | c.3878C>A p.A1293D | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); called by muse, varscan2
- OSMR | c.2543C>T p.S848F | Missense Mutation (SNP) | VAF 73/392 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- PTPN14 | c.1948G>C p.V650L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- PTPRF | c.1595G>T p.W532L | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPRF | c.1596G>T p.W532C | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RABEP2 | c.1633G>C p.A545P | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RBM10 | c.685_695del p.R229Vfs*68 | Frame Shift Del (DEL) | VAF 64/520 reads (12%) | called by mutect2, pindel
- SYCP1 | c.1123T>A p.F375I | Missense Mutation (SNP) | VAF 56/230 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- TENM1 | c.3512T>C p.I1171T | Missense Mutation (SNP) | VAF 81/434 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TMEM102 | c.340C>G p.H114D | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TSPOAP1 | c.1974C>G p.F658L | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- TTN | c.28919C>A p.T9640K (on ENST00000591111; = p.T8713K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/288 reads (3%) | PolyPhen benign (0.187); called by muse, mutect2
- UBE2Z | c.1001A>T p.E334V | Missense Mutation (SNP) | VAF 61/340 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- WDR17 | c.1570G>T p.V524L | Missense Mutation (SNP) | VAF 32/373 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- AMELX | c.324C>T p.S108= | Silent (SNP) | VAF 123/519 reads (24%) | catalogued as rs777235911, COSV61625409; called by muse, mutect2, varscan2
- CHKA | c.387A>C p.L129= | Silent (SNP) | VAF 12/242 reads (5%) | called by muse, mutect2
- DMD | c.2607G>A p.Q869= | Silent (SNP) | VAF 40/750 reads (5%) | called by muse, mutect2
- GCGR | c.552C>T p.F184= | Silent (SNP) | VAF 41/198 reads (21%) | catalogued as rs749874976; called by muse, mutect2, varscan2
- HOXA11 | c.603G>C p.R201= | Silent (SNP) | VAF 12/126 reads (10%) | called by muse, mutect2
- ISYNA1 | c.1584G>A p.L528= | Silent (SNP) | VAF 11/240 reads (5%) | called by muse, mutect2
- OR10H1 | c.807G>T p.L269= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs756619108; called by muse, mutect2
- PKN3 | c.1302T>G p.S434= | Silent (SNP) | VAF 15/181 reads (8%) | called by muse, mutect2
- SERPINB10 | c.750G>T p.L250= | Silent (SNP) | VAF 36/632 reads (6%) | catalogued as COSV53072665; called by muse, mutect2
- ZNF81 | c.186C>T p.F62= | Silent (SNP) | VAF 126/459 reads (27%) | catalogued as rs1333973733, COSV58576064; called by muse, mutect2, varscan2
- CAPN1 | chr11:65214373 C>T | 3'Flank (SNP) | VAF 6/117 reads (5%) | catalogued as rs941674844; called by muse, mutect2
- SLC14A1 | c.-22+2385del | Intron (DEL) | VAF 11/66 reads (17%) | called by mutect2, pindel, varscan2
- USH2A | c.4627+14A>C | Intron (SNP) | VAF 22/234 reads (9%) | called by muse, mutect2
